Somatic mutation profile of tumor specimen MP2PRT-PAPIZN-TMP1-A (aliquot MP2PRT-PAPIZN-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPIZN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.1 years (3,328 days).
Specimen MP2PRT-PAPIZN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2a1803e-78d1-4f93-a4a0-e157e987b2ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPIZN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPIZN-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d179ebf-1a66-4872-86f8-3e585010db84

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, In Frame Ins 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1E | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 155/333 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760975849, COSV62380904; called by muse, mutect2, varscan2
- IGHV3-66 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.099); catalogued as rs377538322; called by muse, varscan2
- IL7R | c.727_728insGGTGCT p.L242_L243insRC | In Frame Ins (INS) | VAF 131/310 reads (42%) | catalogued as COSV57406244, COSV57406538, COSV57408312, COSV57408637, COSV57411199, COSV57411469, COSV57413100, COSV99073420; called by mutect2, pindel, varscan2
- LAMB1 | c.3200G>A p.R1067H | Missense Mutation (SNP) | VAF 251/539 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs549235917, COSV55963470; called by muse, mutect2, varscan2
- MZT1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 113/252 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1376719375; called by muse, mutect2, varscan2
- NCKAP5 | c.5197C>T p.R1733C | Missense Mutation (SNP) | VAF 182/413 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202084151; called by muse, mutect2, varscan2
- TRPC4 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 113/313 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs749513740; called by muse, mutect2, varscan2
- AGPAT1 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 205/463 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKI | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 124/274 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- GAL3ST1 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 333/736 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- HSPA12A | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 197/465 reads (42%) | called by muse, mutect2, varscan2
- LMTK3 | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 164/358 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MED16 | c.1564C>T p.L522F | Missense Mutation (SNP) | VAF 146/302 reads (48%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4K3 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 158/798 reads (20%) | called by mutect2, varscan2
- ZNF844 | c.1921_1922insCCC p.N640_H641insP | In Frame Ins (INS) | VAF 126/310 reads (41%) | called by mutect2, pindel, varscan2
- ADGRF5 | c.3057G>A p.G1019= | Silent (SNP) | VAF 205/453 reads (45%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.537G>A p.L179= | Silent (SNP) | VAF 415/440 reads (94%) | catalogued as COSV100758627; called by muse, mutect2, varscan2
- KCNB1 | c.1212G>A p.V404= | Silent (SNP) | VAF 162/346 reads (47%) | catalogued as rs978719526; called by muse, mutect2, varscan2
- RTL1 | c.3615C>T p.T1205= | Silent (SNP) | VAF 256/543 reads (47%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+1984G>T | Intron (SNP) | VAF 151/317 reads (48%) | called by muse, mutect2, varscan2
